Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4163, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4163-01A (Primary Tumor).

[page 1 of 3]
Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

Right renal tumor.

Specimens Submitted:

1: SP: Right kidney

2: SP: Paracaval lymph nodes

DIAGNOSIS:

1) KIDNEY, RIGHT; NEPHRECTOMY:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE WITH FOCAL SPINDLE CELL FEATURES, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR'S GREATEST DIAMETER IS 8.0 CM.
- FOCALLY, THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- ANGIOMYOLIPOMA, SMOOTH MUSCLE PREDOMINANT (0.6 CM; SEE NOTE).
- THE ADRENAL GLAND IS NOT SUBMITTED.

NOTE: IMMUNOHISTOCHEMICAL STUDIES OF THE ANGIOMYOLIPOMA ARE POSITIVE FOR SMA, FOCALLY POSITIVE FOR HMB-45 AND NEGATIVE FOR S-100 PROTEIN.

2) PARACAVAL LYMPH NODE; RESECTION:

- NINE BENIGN LYMPH NODES (0/9).

Gross Description:

1) The specimen is received fresh for frozen section, labeled, "Right kidney". It consists of product of right radical nephrectomy which weighs 490 grams and measures 14.0 from

[page 2 of 3]
[REDACTED]

superior to inferior, 8.5 cm from medial to lateral and 5.5 cm from anterior to posterior. The soft tissue margins are inked blue. The specimen is bivalved revealing a fleshy mass in the superior pole which measures 8.0 x 6.5 x 3.0 cm. Portions of the tumor are yellow-orange and lobulated. In other regions, the tumor is homogenous, tan and firm. Approximately 25% of the tumor is composed of yellow-orange tumor and approximately 75% of the tumor has a homogenous tan appearance. Soft tissue margins are freely movable over the mass. The remaining renal parenchyma is tan-brown and unremarkable. The cortical thickness measure between 0.4 and 0.6 cm in thickness. The capsule strips with ease over the unremarkable parenchyma but is focally adherent in the region of the tumor. There is a 7.0 cm segment of ureter attached. The tumor does not involve the medullary cavity. The renal vein and artery are free of tumor. On serial sectioning, in the anterior aspect in the inferior pole, is a small, firm white nodule which measure 0.6 cm in greatest dimension. This distinct nodule is located about 1.5 cm from the main tumor. Serial sectioning of the remaining of the large tumor mass reveals areas of hemorrhage and variable areas of necrosis. Examination of the hilar adipose tissue reveals no lymph nodes.

Summary of Sections:

FSC - frozen section control

T - tumor

RP - renal parenchyma

N - nodule

VM - vascular margin

UM - ureteral margin

[REDACTED]

2) The specimen is received in formalin, labeled, "Paracaval Lymph Nodes". It consists of a fragment of adipose tissue, measuring 4.0 x 2.2 x 1.5 cm. Cut-section shows a few lymph nodes, the largest measuring 2.5 cm in diameter. The larger lymph node is bisected. The specimen is submitted in three cassettes.

Summary of Sections:

BLN - bisected lymph nodes

LN - lymph nodes

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
SMOOTH MUSCLE ACTIN		
MELANOMA-E (HMB-45)		
S100 PROTEIN		
IMMUNO RECU		
NEGATIVE CONTROL		
MELANOMA-E (HMB-45)		
NEGATIVE CONTROL		

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
------	-------	------	--------	--------	-----

[page 3 of 3]
[REDACTED]

1	FSC	1	1	N
	N	1	1	
	RP	1	1	
	T	6	M	
	UM	1	1	
	VM	1	1	
2	BLN	1	1	
	LN	2	2	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 49548054-3a09-48c9-8473-c24f9dca6440 (TCGA-BP-4163.E50AB646-C56E-4A9F-B457-B9BEB1D929C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).